Somatic mutation profile of tumor specimen ALCH-AE62-TTP1-A (aliquot ALCH-AE62-TTP1-A-1-0-D-A604-36) from ALCHEMIST case ALCH-AE62, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.1 years (21,572 days).
Specimen ALCH-AE62-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87270bbd-8b66-4f73-881c-4219c636b0cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE62-NB1-A (Blood Derived Normal), aliquot ALCH-AE62-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f4184f9-46ba-49a3-bb2c-1cf42a2090f5

The open-access MAF lists 111 somatic variants for this specimen: 76 protein-altering or splice-affecting, 27 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 27, Intron 5, Splice Site 5, Nonsense Mutation 4, Splice Region 2, Frame Shift Del 1, 3'Flank 1, Frame Shift Ins 1, In Frame Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2254del p.L747_T751del | In Frame Del (DEL) | VAF 343/1332 reads (26%) | hotspot (GDC flag); catalogued as rs121913442, COSV51863059; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.673-2A>T p.X225_splice | Splice Site (SNP) | VAF 89/517 reads (17%) | hotspot (GDC flag); catalogued as CS109519, COSV52669186, COSV52682653, COSV52687702; called by muse, mutect2, varscan2
- ABCE1 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV56847899; called by muse, mutect2, varscan2
- ACTG2 | c.810G>T p.M270I | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.357); catalogued as COSV61828213; called by muse, varscan2
- AREL1 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1319027008; called by muse, mutect2, varscan2
- C1orf131 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs772202745; called by muse, mutect2
- CAT | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 223/1510 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs139875365; called by muse, mutect2, varscan2
- CDC20B | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 38/565 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs142234339, COSV99697054; called by muse, mutect2
- CLASP1 | c.1512A>G p.I504M | Missense Mutation (SNP) | VAF 26/307 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.83); catalogued as rs766538890; called by muse, mutect2
- CMTR1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 185/841 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); catalogued as COSV65091802; called by muse, mutect2, varscan2
- CNTN6 | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV63183394; called by muse, mutect2
- COL20A1 | c.2836C>T p.R946C | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs368681298; called by muse, mutect2, varscan2
- CSMD3 | c.5776G>T p.A1926S (on ENST00000297405 / NM_001363185.1; = p.A1822S on NM_052900.3) | Missense Mutation (SNP) | VAF 89/451 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as rs1285621248, COSV52202270; called by muse, mutect2, varscan2
- CSMD3 | c.5775G>T p.L1925F (on ENST00000297405 / NM_001363185.1; = p.L1821F on NM_052900.3) | Missense Mutation (SNP) | VAF 90/456 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs538253389; called by muse, mutect2, varscan2
- FASTKD2 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768295259; called by muse, mutect2, varscan2
- FLG | c.5686A>G p.R1896G | Missense Mutation (SNP) | VAF 62/1182 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1178354525; called by muse, mutect2
- FUT3 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.591); catalogued as COSV54607844; called by muse, mutect2, varscan2
- GABRG3 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 27/371 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61519612; called by muse, mutect2
- GC | c.129-1G>T p.X43_splice | Splice Site (SNP) | VAF 45/217 reads (21%) | catalogued as rs112961993, COSV56735294; called by muse, mutect2, varscan2
- HACL1 | c.1271del p.G424Efs*42 | Frame Shift Del (DEL) | VAF 31/297 reads (10%) | catalogued as rs1437453135; called by mutect2, pindel, varscan2
- KCTD16 | c.902G>T p.G301V | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1179809465, COSV72580130; called by muse, mutect2
- KIF26B | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs765840647; called by muse, mutect2
- KRTAP11-1 | c.308C>A p.P103Q | Missense Mutation (SNP) | VAF 68/894 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60094064; called by muse, mutect2
- MINK1 | c.3731T>G p.I1244S | Missense Mutation (SNP) | VAF 38/351 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as rs758096782; called by muse, mutect2, varscan2
- MUC16 | c.40740G>C p.E13580D | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.878); catalogued as COSV101109566, COSV66694776; called by muse, mutect2, varscan2
- NCLN | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 12/378 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV55742324; called by muse, mutect2
- NDUFA13 | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 51/509 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.881); catalogued as rs752746010; called by muse, mutect2, varscan2
- NLRP14 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 98/1262 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1202573355; called by muse, mutect2
- PLAUR | c.76A>T p.M26L | Missense Mutation (SNP) | VAF 25/405 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs762840398; called by muse, mutect2
- PROX1 | c.1485C>A p.S495R | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as rs759885337; called by muse, mutect2, varscan2
- PYGB | c.1092+1G>T p.X364_splice | Splice Site (SNP) | VAF 44/240 reads (18%) | catalogued as rs199886979; called by muse, mutect2, varscan2
- SEMA6A | c.2374C>A p.P792T | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs779770223, COSV56711653; called by muse, mutect2
- ZNF735 | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 87/385 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70036271; called by muse, mutect2, varscan2
- ZNF804A | c.2257G>T p.A753S | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0.018); catalogued as COSV56474776; called by muse, mutect2, varscan2
- AHRR | c.909-3C>A | Splice Region (SNP) | VAF 46/620 reads (7%) | called by muse, mutect2
- AMPD2 | c.2255G>T p.G752V | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD300LG | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDK5RAP1 | c.1726-3C>G | Splice Region (SNP) | VAF 12/291 reads (4%) | called by muse, mutect2
- CEP170B | c.3077C>A p.P1026Q (on ENST00000453495; = p.P955Q on NM_015005.3) | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- COL21A1 | c.805A>T p.T269S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DMXL1 | c.4945A>C p.K1649Q | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DOCK1 | c.3060+1G>T p.X1020_splice | Splice Site (SNP) | VAF 77/320 reads (24%) | called by muse, mutect2, varscan2
- FAM216A | c.307-2A>G p.X103_splice | Splice Site (SNP) | VAF 11/97 reads (11%) | called by mutect2, varscan2
- FAT3 | c.9974C>A p.A3325D | Missense Mutation (SNP) | VAF 60/538 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.25); called by muse, varscan2
- FBLN2 | c.1594G>T p.G532C | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- H1-7 | c.272G>C p.R91P | Missense Mutation (SNP) | VAF 52/470 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- HEG1 | c.1094T>C p.I365T | Missense Mutation (SNP) | VAF 24/839 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- HERC2 | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HYAL2 | c.1177A>C p.S393R | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- IGHG1 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 107/869 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- LAMC3 | c.1502T>A p.L501H | Missense Mutation (SNP) | VAF 169/866 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LCA5 | c.41G>C p.R14T | Missense Mutation (SNP) | VAF 34/658 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- MRPS34 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 117/674 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYBPC1 | c.1920G>T p.W640C (on ENST00000550270 / NM_206820.2; = p.W665C on NM_002465.4) | Missense Mutation (SNP) | VAF 54/528 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH14 | c.4931A>T p.E1644V | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- NAV3 | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 41/561 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- NLRP4 | c.1720C>A p.Q574K | Missense Mutation (SNP) | VAF 26/439 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.365); called by muse, mutect2
- NLRP9 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.928); called by muse, mutect2
- OR52E4 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 67/563 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- OR5H14 | c.470T>C p.L157S | Missense Mutation (SNP) | VAF 19/380 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.081); called by muse, mutect2
- OTOG | c.5831C>T p.T1944I | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PKHD1L1 | c.10302C>A p.Y3434* | Nonsense Mutation (SNP) | VAF 52/235 reads (22%) | called by muse, mutect2, varscan2
- RNF144B | c.677dup p.L226Ffs*3 | Frame Shift Ins (INS) | VAF 40/292 reads (14%) | called by mutect2, pindel, varscan2
- SEMA6C | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 125/661 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SETD4 | c.636G>T p.R212S | Missense Mutation (SNP) | VAF 104/724 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC16A14 | c.991G>T p.V331F | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- ST14 | c.1297C>T p.Q433* | Nonsense Mutation (SNP) | VAF 30/1094 reads (3%) | called by muse, mutect2
- TBX1 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 50/660 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.052); called by muse, mutect2
- TNFSF13B | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 83/502 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRPS1 | c.1175G>T p.G392V (on ENST00000220888 / NM_001330599.2; = p.G405V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/338 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.222); called by muse, mutect2
- TRPS1 | c.1174G>T p.G392* (on ENST00000220888 / NM_001330599.2; = p.G405* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/340 reads (9%) | called by muse, mutect2
- TRPV2 | c.80G>A p.R27K | Missense Mutation (SNP) | VAF 20/508 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TSPAN17 | c.889G>T p.G297W | Missense Mutation (SNP) | VAF 69/396 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- XDH | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 185/904 reads (20%) | called by muse, mutect2, varscan2
- ZNF658 | c.2086G>T p.A696S | Missense Mutation (SNP) | VAF 69/615 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF708 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ADAMTS13 | c.2700G>A p.A900= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs782742222, COSV63023473; called by muse, mutect2
- AHNAK2 | c.3171C>G p.V1057= | Silent (SNP) | VAF 160/552 reads (29%) | called by muse, mutect2, varscan2
- ATXN7 | c.1194G>A p.L398= | Silent (SNP) | VAF 26/319 reads (8%) | called by muse, mutect2
- CCDC168 | c.18681A>T p.A6227= | Silent (SNP) | VAF 30/392 reads (8%) | catalogued as rs1358742654; called by muse, mutect2
- COL4A1 | c.636C>T p.G212= | Silent (SNP) | VAF 30/320 reads (9%) | called by muse, mutect2
- CRB2 | c.1407G>A p.L469= | Silent (SNP) | VAF 82/362 reads (23%) | called by muse, mutect2, varscan2
- CYP3A5 | c.252C>A p.I84= | Silent (SNP) | VAF 34/640 reads (5%) | called by muse, mutect2
- DCLK2 | c.597G>T p.V199= | Silent (SNP) | VAF 150/785 reads (19%) | called by muse, mutect2, varscan2
- DSC3 | c.849C>T p.S283= | Silent (SNP) | VAF 94/984 reads (10%) | called by muse, mutect2
- DUSP29 | c.306C>T p.R102= | Silent (SNP) | VAF 28/619 reads (5%) | catalogued as COSV58300317; called by muse, mutect2
- FAT3 | c.9975C>T p.A3325= | Silent (SNP) | VAF 60/537 reads (11%) | called by muse, varscan2
- GLIPR1L2 | c.97C>T p.L33= | Silent (SNP) | VAF 63/678 reads (9%) | catalogued as rs762962565; called by muse, mutect2
- GPC6 | c.612C>A p.P204= | Silent (SNP) | VAF 30/374 reads (8%) | catalogued as COSV65538983; called by muse, mutect2
- GRIK5 | c.411C>T p.S137= | Silent (SNP) | VAF 42/523 reads (8%) | called by muse, mutect2
- INSM1 | c.54C>T p.Y18= | Silent (SNP) | VAF 9/154 reads (6%) | catalogued as rs981649540; called by muse, mutect2
- INSM1 | c.1107C>T p.C369= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as COSV59605517; called by muse, mutect2
- KCNS2 | c.327C>A p.G109= | Silent (SNP) | VAF 58/846 reads (7%) | called by muse, mutect2
- MUC2 | c.195C>T p.S65= | Silent (SNP) | VAF 23/193 reads (12%) | catalogued as rs771628651; called by muse, mutect2, varscan2
- NEURL3 | c.174C>A p.G58= | Silent (SNP) | VAF 48/234 reads (21%) | called by muse, mutect2, varscan2
- NF1 | c.555G>T p.V185= | Silent (SNP) | VAF 91/440 reads (21%) | called by muse, mutect2, varscan2
- NPSR1 | c.1056G>T p.T352= | Silent (SNP) | VAF 33/523 reads (6%) | catalogued as rs143448171; called by muse, mutect2
- OR14I1 | c.600G>T p.L200= | Silent (SNP) | VAF 95/597 reads (16%) | called by muse, mutect2, varscan2
- SH3TC2 | c.3154C>A p.R1052= | Silent (SNP) | VAF 78/739 reads (11%) | catalogued as rs370115218, CM1411888, COSV60462716; called by muse, mutect2, varscan2
- TACC3 | c.60C>T p.C20= | Silent (SNP) | VAF 42/464 reads (9%) | catalogued as rs764314226, COSV57559412; called by muse, mutect2
- TERT | c.2886C>T p.R962= | Silent (SNP) | VAF 54/1010 reads (5%) | catalogued as rs542440625, COSV104395509; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2
- TSPAN17 | c.888G>T p.A296= | Silent (SNP) | VAF 68/395 reads (17%) | called by muse, mutect2, varscan2
- USP29 | c.1206G>T p.G402= | Silent (SNP) | VAF 28/298 reads (9%) | catalogued as COSV54146331; called by muse, mutect2
- AC136759.1 | n.1215C>G | RNA (SNP) | VAF 114/1364 reads (8%) | catalogued as rs571653212; called by muse, mutect2
- ATP6V1G3 | c.82+3880G>T | Intron (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- CACNA1G | c.*68A>G | 3'UTR (SNP) | VAF 55/517 reads (11%) | called by muse, mutect2, varscan2
- CRISP2 | c.515+89A>T | Intron (SNP) | VAF 45/193 reads (23%) | called by muse, mutect2, varscan2
- IL2RB | c.204-71T>A | Intron (SNP) | VAF 28/237 reads (12%) | called by muse, mutect2, varscan2
- KANSL2 | c.1348-243C>T | Intron (SNP) | VAF 18/426 reads (4%) | called by muse, mutect2
- PCDHB6 | chr5:141157328 G>A | 3'Flank (SNP) | VAF 91/1484 reads (6%) | catalogued as rs1331948730; called by muse, mutect2
- PHPT1 | c.285+55C>G | Intron (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
